Gene-level copy-number profile of tumor specimen TCGA-CV-7255-01A from TCGA case TCGA-CV-7255, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 32.7 years (11,931 days).
Specimen TCGA-CV-7255-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.3fb5b680-d214-4ad1-8fbd-17b5d50343bd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7255-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5ddaace7-9821-4cb2-ba0e-907def1d7fdd

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 20; copy number 2: 7,972; copy number 3: 21,122; copy number 4: 7,636; copy number 5: 15,980; copy number 6: 5,145; copy number 7: 1,549; copy number 8: 214; copy number 9: 6; copy number 11: 91; copy number 12: 33; copy number 17: 9; copy number 37: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7255-01A-11D-2010-01): tumor purity 0.65, ploidy 3.52, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:31,704,058–31,796,175, 2 genes: OSBPL10-AS1, ZNF587P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,927 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–49,246,915, 735 genes, copy number 7 (broad region; genes not listed).
- chr6:60,719,222–61,241,311, 6 genes, copy number 9: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1.
- chr8:46,028,804–47,202,897, 30 genes, copy number 7: AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1.
- chr8:82,862,779–140,635,633, 778 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr9:33,676,785–36,304,924, 139 genes, copy number 8 (broad region; genes not listed).
- chr13:24,566,843–28,295,335, 91 genes, copy number 11 (within-gene range 2–11) (broad region; genes not listed).
- chr13:36,168,217–38,545,299, 39 genes, copy number 7–12 (within-gene range 2–12): SOHLH2, CCDC169-SOHLH2, CCDC169, RNU6-71P, SPART, SPART-AS1, CCNA1, H2ACP1, SERTM1, GAPDHP34, TCEAL4P1, ARL2BPP3, NDE1P2, RFXAP, SMAD9, SMAD9-IT1, LAMTOR3P1, RPL29P28, EIF4A1P5, ALG5, EXOSC8, SUPT20H, CSNK1A1L, AL356274.1, AL356274.2, RN7SKP1, RPS12P24, LINC01048, LINC00547, POSTN, TRPC4, RNA5SP26, AL356495.1, LINC02334, HSPD1P9, LINC00571, UFM1, AL356863.1, LINC00437.
- chr13:72,453,902–74,830,080, 34 genes, copy number 17–37: AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347, RIOK3P1.
- chr14:22,066,016–22,518,871, 75 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 20. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
